FM case AD10113 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/e5f949e5-47db-4d40-ae98-96220db6c464

Female, 55.5 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the gastrointestinal tract; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
